Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A3UK, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A3UK-01A (Primary Tumor).

[page 1 of 3]
HIFAA Discrepancy		

Date of Procedure: _____
Date of Receipt: _____
Date of Report: _____
Account #: _____
Billing Type: _____
Additional Copy to: _____

Clinical Diagnosis & History:

Left lobe, papillary carcinoma.

Specimens Submitted:

- 1: Right para-tracheal tissue (fs)
- 2: Total thyroid

DIAGNOSIS:

1. Right para-tracheal tissue; excision:
- One (0/1) benign lymph node.
2. Total thyroid:
- Part # 2
- Tumor Type:
- Papillary carcinoma, classical type
- Histologic Grade:
- Well differentiated
- Mitotic Activity:
- Not identified
- Tumor Necrosis:
- Not identified
- Tumor Location:
- Left lobe
- Tumor Size:
- Greatest diameter is 1.5 cm.
- Tumor Encapsulation:
- Completely surrounded
- Capsular Invasion:
- Not identified
- Blood Vessel Invasion:
- Not identified
- Extrathyroid Extension:
- Not identified
- Surgical Margins:
- Free of tumor
- Tumor Multicentricity:
- Not identified

ICD-O-3

carcinoma, papillary, thyroid

8240/3

Site: thyroid, NOS

C73.9

5-2-12

RD

[page 2 of 3]
Non-Neoplastic Thyroid:
Exhibits nodular hyperplasia
Parathyroid Glands:
Identified
One intrathyroidal parathyroid gland

Lymph Nodes:
Two (0/2) benign lymph nodes

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1). The specimen is received fresh for frozen section consultation, labeled "right paratracheal tissue" and consists of a piece of soft tissue measuring 0.7 x 0.4 x 0.2 cm. The specimen is entirely submitted for frozen section.

Summary of sections:
FSC - frozen section control

2). The specimen is received fresh, labeled "total thyroid, stitch marks left lobe", and consists of a thyroid weighing 14 g. The right lobe measures 3.5 x 1.5 x 0.6 cm, the left lobe measures 3.5 x 1.5 x 0.8 cm and the isthmus measures 1.5 x 0.6 x 0.4 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. The anterior surface of the isthmus is inked green. Sectioning reveals a tan circumscribed nodule in the left lower lobe. The nodule is located in the left lower lobe, measures 1.5 x 1 x 1 cm, displays tan-brown, firm cut surfaces, and is encapsulated. Sections through the remaining tissue reveal unremarkable red-brown and beefy parenchyma. The remaining thyroid parenchyma is red brown and beefy. Representative sections of the specimen are submitted for . The remaining thyroid tissue is serially sectioned and entirely submitted.

Summary of sections:
N - left lobe nodule, entirely submitted
RL - right lobe
LL - left lobe
IS - isthmus
LSK-left skeletal muscle, representative
RSK-right skeletal muscle, representative

Summary of Sections:

Part 1: Right para-tracheal tissue (fs)

Block	Sect. Site	PCs
1	fsc	1

Part 2: Total thyroid

Block	Sect. Site	PCs
2	IS	2
1	LL	1
1	LSK	1
4	N	4
4	RL	4
1	RSK	1

[page 3 of 3]
Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: One benign lymph node (0/1)
PERMANENT DIAGNOSIS: Same.

Source: NCI Genomic Data Commons file c6483632-0508-49e1-bf4a-7d7bf6958a9e (TCGA-DJ-A3UK.C4494D77-7172-4C95-95D4-CFCC3A0F66C5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).